Somatic mutation profile of tumor specimen TCGA-CV-7091-01A (aliquot TCGA-CV-7091-01A-11D-2012-08) from TCGA case TCGA-CV-7091, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Overlapping lesion of lip, oral cavity and pharynx; AJCC pathologic stage: Stage I; Tumor grade: G3; Age at diagnosis: 54.6 years (19,938 days).
Specimen TCGA-CV-7091-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1a7c9bd5-10ab-4d2f-98e1-755156c9ec3e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CV-7091-10A (Blood Derived Normal), aliquot TCGA-CV-7091-10A-01D-2013-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6ca741b7-269b-4b9b-b94c-339a48e37fb4

The open-access MAF lists 142 somatic variants for this specimen: 110 protein-altering or splice-affecting, 30 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 89, Silent 30, Nonsense Mutation 8, Splice Site 4, Frame Shift Del 3, Frame Shift Ins 3, 5'Flank 2, In Frame Del 1, Nonstop Mutation 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- A1BG | c.723C>A p.F241L | Missense Mutation (SNP) | VAF 15/39 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV99568591; called by muse, mutect2, varscan2
- ACTN3 | c.1334G>T p.R445L | Missense Mutation (SNP) | VAF 10/62 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0.322); catalogued as COSV100074459; called by muse, mutect2, varscan2
- ADGRE5 | c.1449+2T>C p.X483_splice (on ENST00000242786 / NM_078481.4; = p.X390_splice on NM_001784.5) | Splice Site (SNP) | VAF 20/73 reads (27%) | catalogued as COSV99663167; called by muse, mutect2, varscan2
- AP002512.3 | c.988C>T p.R330C | Missense Mutation (SNP) | VAF 7/17 reads (41%) | SIFT deleterious (0.02); PolyPhen benign (0.018); catalogued as rs199694619, COSV54405850; called by muse, mutect2, varscan2
- ARFGEF1 | c.3188G>C p.G1063A | Missense Mutation (SNP) | VAF 18/58 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV99144031; called by muse, mutect2, varscan2
- ATP13A3 | c.2280A>T p.R760S | Missense Mutation (SNP) | VAF 10/61 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.849); catalogued as COSV99757502; called by muse, mutect2, varscan2
- AZI2 | c.1073G>A p.S358N | Missense Mutation (SNP) | VAF 33/79 reads (42%) | SIFT tolerated (0.54); PolyPhen benign (0.011); catalogued as rs749558733, COSV99843731; called by muse, mutect2, varscan2
- BLNK | c.541C>A p.P181T | Missense Mutation (SNP) | VAF 8/43 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.152); catalogued as COSV99814141; called by muse, mutect2
- CALCOCO1 | c.1864C>G p.P622A | Missense Mutation (SNP) | VAF 34/112 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.696); catalogued as COSV100017447; called by muse, mutect2, varscan2
- CASZ1 | c.1313T>A p.I438N | Missense Mutation (SNP) | VAF 14/76 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV100682028; called by muse, mutect2, varscan2
- CD40 | c.571C>T p.R191W | Missense Mutation (SNP) | VAF 16/125 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1361629901, COSV100953861; called by muse, mutect2, varscan2
- CDH7 | c.2062C>T p.P688S | Missense Mutation (SNP) | VAF 13/56 reads (23%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.999); catalogued as COSV100543023; called by muse, mutect2, varscan2
- COG4 | c.287A>G p.K96R | Missense Mutation (SNP) | VAF 31/97 reads (32%) | SIFT tolerated (0.37); PolyPhen benign (0.003); catalogued as COSV100092165; called by muse, mutect2, varscan2
- COL11A1 | c.1549C>G p.Q517E | Missense Mutation (SNP) | VAF 9/43 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.9); catalogued as COSV100617839; called by muse, mutect2, varscan2
- COL22A1 | c.3613G>T p.A1205S | Missense Mutation (SNP) | VAF 41/161 reads (25%) | SIFT tolerated (0.75); PolyPhen benign (0.393); catalogued as COSV100280105; called by muse, mutect2, varscan2
- COL5A2 | c.3527G>A p.G1176D | Missense Mutation (SNP) | VAF 29/106 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100880668; called by muse, mutect2
- CPSF6 | c.1655A>G p.*552Wext*30 | Nonstop Mutation (SNP) | VAF 6/38 reads (16%) | catalogued as COSV99879626; called by muse, mutect2
- CSMD3 | c.9873T>A p.C3291* (on ENST00000297405 / NM_001363185.1; = p.C3122* on NM_052900.3) | Nonsense Mutation (SNP) | VAF 11/69 reads (16%) | catalogued as COSV99843949; called by muse, mutect2, varscan2
- CTNNA2 | c.577A>G p.R193G | Missense Mutation (SNP) | VAF 19/93 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.803); catalogued as COSV100782120, COSV100785566; called by muse, mutect2, varscan2
- CX3CL1 | c.779T>A p.L260Q | Missense Mutation (SNP) | VAF 23/70 reads (33%) | SIFT tolerated (0.07); PolyPhen benign (0.014); catalogued as COSV99136463; called by muse, mutect2, varscan2
- CYP4F2 | c.1463G>A p.R488H | Missense Mutation (SNP) | VAF 9/87 reads (10%) | SIFT tolerated (0.06); PolyPhen benign (0.178); catalogued as rs1388353329, COSV55620300; called by muse, mutect2, varscan2
- DNAH7 | c.8716G>T p.G2906W | Missense Mutation (SNP) | VAF 22/46 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100416916; called by muse, mutect2, varscan2
- DPP3 | c.1477G>C p.E493Q | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.651); catalogued as COSV100855694; called by muse, mutect2
- DSEL | c.897G>C p.Q299H | Missense Mutation (SNP) | VAF 16/88 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100025980; called by muse, mutect2, varscan2
- ERC1 | c.1738A>C p.I580L (on ENST00000360905 / NM_178040.4; = p.I552L on NM_178039.4) | Missense Mutation (SNP) | VAF 17/49 reads (35%) | SIFT tolerated (0.08); PolyPhen benign (0.208); catalogued as COSV100706569; called by muse, varscan2
- FAT1 | c.3208C>T p.R1070* | Nonsense Mutation (SNP) | VAF 55/134 reads (41%) | catalogued as rs1183516785, COSV71674659; called by muse, mutect2, varscan2
- FBXO31 | c.1507C>G p.L503V | Missense Mutation (SNP) | VAF 13/39 reads (33%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.994); catalogued as rs1243958041, COSV100291559; called by muse, mutect2, varscan2
- FCHSD1 | c.802C>T p.H268Y | Missense Mutation (SNP) | VAF 9/20 reads (45%) | SIFT deleterious (0.02); PolyPhen benign (0.071); catalogued as COSV101447605; called by muse, mutect2
- FCRL4 | c.521A>T p.N174I | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT tolerated (0.31); PolyPhen benign (0.425); catalogued as COSV54861582, COSV99620279; called by muse, mutect2, varscan2
- GDF3 | c.277C>A p.L93I | Missense Mutation (SNP) | VAF 28/87 reads (32%) | SIFT tolerated (0.45); PolyPhen benign (0.046); catalogued as COSV61712496; called by muse, mutect2, varscan2
- HIC2 | c.899G>T p.G300V | Missense Mutation (SNP) | VAF 18/59 reads (31%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.454); catalogued as COSV101335533, COSV101335615, COSV68042195; called by muse, mutect2, varscan2
- ILDR1 | c.1489C>T p.R497C (on ENST00000344209 / NM_001199799.2; = p.R453C on NM_175924.4) | Missense Mutation (SNP) | VAF 13/45 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.353); catalogued as rs371286984; called by muse, mutect2, varscan2
- ISL2 | c.43G>A p.G15S | Missense Mutation (SNP) | VAF 59/426 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.309); catalogued as rs749841412, COSV99320835; called by muse, mutect2, varscan2
- ITPA | c.466C>T p.Q156* | Nonsense Mutation (SNP) | VAF 13/58 reads (22%) | catalogued as COSV101200050; called by muse, mutect2, varscan2
- KCNB2 | c.2498G>C p.C833S | Missense Mutation (SNP) | VAF 23/81 reads (28%) | SIFT tolerated, low confidence (0.48); PolyPhen benign (0.003); catalogued as COSV101578932; called by muse, mutect2, varscan2
- KIRREL1 | c.186G>C p.M62I | Missense Mutation (SNP) | VAF 44/158 reads (28%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV100780066; called by muse, mutect2, varscan2
- KLHL1 | c.785C>T p.A262V | Missense Mutation (SNP) | VAF 22/57 reads (39%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.859); catalogued as rs139916031; called by muse, mutect2, varscan2
- LCP1 | c.1384T>G p.Y462D | Missense Mutation (SNP) | VAF 11/40 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100550027; called by muse, mutect2, varscan2
- LMBRD2 | c.774C>G p.I258M | Missense Mutation (SNP) | VAF 7/42 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); catalogued as COSV99683149; called by muse, mutect2
- LTBP1 | c.1330C>T p.Q444* (on ENST00000404816 / NM_206943.4; = p.Q118* on NM_000627.4) | Nonsense Mutation (SNP) | VAF 18/71 reads (25%) | catalogued as rs866362378, COSV100617829; called by muse, mutect2, varscan2
- LUZP4 | c.502A>G p.R168G | Missense Mutation (SNP) | VAF 42/62 reads (68%) | SIFT deleterious (0.01); PolyPhen benign (0.222); catalogued as COSV100904868; called by muse, mutect2, varscan2
- MDH1B | c.1427C>T p.P476L | Missense Mutation (SNP) | VAF 21/49 reads (43%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0); catalogued as COSV100982269; called by muse, mutect2, varscan2
- MTR | c.3711+2T>C p.X1237_splice | Splice Site (SNP) | VAF 19/120 reads (16%) | catalogued as COSV100855502; called by muse, mutect2
- MUC16 | c.31951G>C p.A10651P | Missense Mutation (SNP) | VAF 14/79 reads (18%) | SIFT tolerated, low confidence (0.09); PolyPhen possibly damaging (0.529); catalogued as COSV101198393, COSV101200948; called by muse, mutect2, varscan2
- MYCBP2 | c.5879C>G p.S1960W (on ENST00000357337; = p.S1998W on NM_015057.5) | Missense Mutation (SNP) | VAF 18/96 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV100631392; called by muse, varscan2
- MYOM2 | c.1832T>C p.V611A | Missense Mutation (SNP) | VAF 116/278 reads (42%) | SIFT tolerated (0.12); PolyPhen benign (0.007); catalogued as COSV100038146; called by muse, mutect2, varscan2
- NAA25 | c.477A>C p.Q159H | Missense Mutation (SNP) | VAF 36/209 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV55708393, COSV99927926; called by muse, mutect2, varscan2
- NAP1L3 | c.1273G>A p.G425R | Missense Mutation (SNP) | VAF 6/10 reads (60%) | SIFT deleterious (0); PolyPhen possibly damaging (0.79); catalogued as COSV100220585; called by muse, mutect2, varscan2
- NEB | c.64G>A p.E22K | Missense Mutation (SNP) | VAF 47/119 reads (39%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.034); catalogued as COSV99426508; called by muse, mutect2, varscan2
- NFE2L1 | c.266C>A p.A89D | Missense Mutation (SNP) | VAF 25/121 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.587); catalogued as COSV100671664; called by muse, mutect2, varscan2
- NIPBL | c.7291A>G p.I2431V | Missense Mutation (SNP) | VAF 14/67 reads (21%) | SIFT tolerated (0.43); PolyPhen benign (0.326); catalogued as COSV99242130; called by muse, mutect2, varscan2
- NLGN1 | c.1022A>T p.E341V | Missense Mutation (SNP) | VAF 44/176 reads (25%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.577); catalogued as COSV100849892; called by muse, mutect2, varscan2
- NLRP7 | c.2713C>A p.L905I (on ENST00000340844 / NM_206828.3; = p.L877I on NM_139176.3) | Missense Mutation (SNP) | VAF 56/128 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100053189; called by muse, mutect2, varscan2
- NPC1L1 | c.590G>T p.C197F | Missense Mutation (SNP) | VAF 23/90 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99213097; called by muse, mutect2, varscan2
- OR2Z1 | c.622A>C p.M208L | Missense Mutation (SNP) | VAF 34/86 reads (40%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100136507; called by muse, mutect2, varscan2
- OR5H14 | c.426C>G p.I142M | Missense Mutation (SNP) | VAF 18/192 reads (9%) | SIFT tolerated (0.07); PolyPhen benign (0.068); catalogued as rs1388335524, COSV101454250; called by muse, mutect2
- PC | c.2675A>G p.K892R | Missense Mutation (SNP) | VAF 12/56 reads (21%) | SIFT tolerated (0.4); PolyPhen benign (0.025); catalogued as COSV100547167, COSV58993157; called by muse, mutect2, varscan2
- PIK3C2B | c.3692G>A p.R1231H | Missense Mutation (SNP) | VAF 8/72 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs370508156; called by mutect2, varscan2
- PIP5K1B | c.1467C>G p.H489Q | Missense Mutation (SNP) | VAF 36/96 reads (38%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0); catalogued as COSV99599544; called by muse, mutect2, varscan2
- POLH | c.1906G>A p.E636K | Missense Mutation (SNP) | VAF 34/177 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.563); catalogued as COSV100947852; called by muse, mutect2, varscan2
- POU4F2 | c.275T>A p.L92H | Missense Mutation (SNP) | VAF 16/43 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.979); catalogued as COSV55585665, COSV99850740; called by muse, mutect2, varscan2
- PRDM16 | c.1178C>T p.P393L | Missense Mutation (SNP) | VAF 16/98 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99578297; called by muse, mutect2, varscan2
- PRSS55 | c.430C>T p.L144F | Missense Mutation (SNP) | VAF 36/202 reads (18%) | SIFT tolerated (0.09); PolyPhen benign (0.007); catalogued as rs1462470172, COSV60807857; called by muse, mutect2, varscan2
- RGL4 | c.22C>G p.L8V | Missense Mutation (SNP) | VAF 24/56 reads (43%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.01); catalogued as COSV99318884; called by muse, mutect2, varscan2
- RGS6 | c.272A>C p.Q91P | Missense Mutation (SNP) | VAF 29/86 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.625); catalogued as COSV100666831; called by muse, mutect2, varscan2
- RNF19A | c.643G>A p.D215N | Missense Mutation (SNP) | VAF 33/97 reads (34%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.998); catalogued as COSV100348015; called by muse, mutect2, varscan2
- RPF1 | c.265A>G p.R89G | Missense Mutation (SNP) | VAF 32/70 reads (46%) | SIFT tolerated (0.11); PolyPhen benign (0.095); catalogued as COSV101039816; called by muse, mutect2, varscan2
- RPTN | c.1104T>A p.S368R | Missense Mutation (SNP) | VAF 170/1033 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.081); catalogued as COSV100285680; called by muse, mutect2, varscan2
- RYR3 | c.5362G>T p.E1788* | Nonsense Mutation (SNP) | VAF 32/239 reads (13%) | catalogued as COSV101213861; called by muse, mutect2, varscan2
- SAT1 | c.118+1G>A p.X40_splice | Splice Site (SNP) | VAF 11/24 reads (46%) | catalogued as COSV100803903; called by muse, mutect2, varscan2
- SCN9A | c.4523T>C p.I1508T (on ENST00000303354; = p.I1497T on NM_002977.3) | Missense Mutation (SNP) | VAF 17/43 reads (40%) | SIFT deleterious (0.02); PolyPhen benign (0.419); catalogued as rs1359777832, COSV100313796; called by muse, mutect2, varscan2
- SEMA4G | c.1652A>G p.E551G (on ENST00000370250; = p.E556G on NM_017893.3) | Missense Mutation (SNP) | VAF 7/73 reads (10%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.456); catalogued as COSV99273058; called by muse, mutect2
- SIAH1 | c.643C>T p.R215C | Missense Mutation (SNP) | VAF 15/82 reads (18%) | SIFT tolerated (0.09); PolyPhen benign (0.092); catalogued as rs979589878, COSV99589447; called by muse, mutect2, varscan2
- SLC22A12 | c.149G>A p.W50* | Nonsense Mutation (SNP) | VAF 13/96 reads (14%) | catalogued as rs1163262384, COSV100327822; called by mutect2, varscan2
- SLC25A13 | c.1325A>T p.Q442L | Missense Mutation (SNP) | VAF 66/143 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99674045; called by muse, mutect2, varscan2
- SLC25A6 | c.114C>G p.V38= | Splice Region (SNP) | VAF 32/244 reads (13%) | catalogued as COSV101195447, COSV101195491, COSV67318090; called by muse, mutect2, varscan2
- SLC27A5 | c.1339C>T p.R447C | Missense Mutation (SNP) | VAF 11/44 reads (25%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.953); catalogued as rs558863851, COSV54022023; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SLC44A2 | c.2015-1G>A p.X672_splice | Splice Site (SNP) | VAF 8/15 reads (53%) | catalogued as COSV100213402; called by muse, mutect2, varscan2
- SLC52A3 | c.515T>C p.I172T | Missense Mutation (SNP) | VAF 16/94 reads (17%) | SIFT tolerated (0.66); PolyPhen benign (0); catalogued as rs774371416, COSV99448272; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SLCO1C1 | c.1086C>A p.S362R | Missense Mutation (SNP) | VAF 29/104 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.921); catalogued as COSV99859745; called by muse, mutect2, varscan2
- SRRM2 | c.7142C>G p.T2381S | Missense Mutation (SNP) | VAF 35/125 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.956); catalogued as COSV99241672; called by muse, mutect2, varscan2
- SVIL | c.844C>G p.H282D | Missense Mutation (SNP) | VAF 10/62 reads (16%) | SIFT tolerated (0.51); PolyPhen benign (0.142); catalogued as COSV100881469, COSV63443927; called by muse, mutect2, varscan2
- TADA2B | c.929C>T p.A310V | Missense Mutation (SNP) | VAF 29/63 reads (46%) | SIFT tolerated (0.28); PolyPhen benign (0.346); catalogued as COSV99380745; called by muse, mutect2, varscan2
- TBC1D5 | c.680C>G p.A227G | Missense Mutation (SNP) | VAF 22/64 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.965); catalogued as COSV99511604; called by muse, mutect2, varscan2
- TECPR2 | c.3771G>C p.M1257I | Missense Mutation (SNP) | VAF 13/62 reads (21%) | SIFT tolerated (0.39); PolyPhen benign (0.091); catalogued as COSV100850167; called by mutect2, varscan2
- TEX10 | c.1628A>G p.Y543C | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT tolerated (0.08); PolyPhen benign (0.258); catalogued as COSV100887935; called by muse, mutect2
- TMEM192 | c.812C>G p.T271R | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.042); catalogued as COSV100122183; called by muse, mutect2, varscan2
- TNFRSF13B | c.7G>T p.G3C | Missense Mutation (SNP) | VAF 14/64 reads (22%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.84); catalogued as COSV99891799; called by muse, varscan2
- TRPS1 | c.616G>A p.V206M (on ENST00000220888 / NM_001330599.2; = p.V219M on NM_014112.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 33/162 reads (20%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.259); catalogued as COSV99633524; called by muse, mutect2, varscan2
- TUBB4B | c.1303G>A p.E435K | Missense Mutation (SNP) | VAF 51/98 reads (52%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.17); catalogued as rs1471667058, COSV100458129; called by muse, mutect2, varscan2
- USP21 | c.101G>A p.R34H | Missense Mutation (SNP) | VAF 44/138 reads (32%) | SIFT tolerated, low confidence (0.06); PolyPhen possibly damaging (0.511); catalogued as rs369560591; called by muse, varscan2
- WRN | c.2532C>A p.D844E | Missense Mutation (SNP) | VAF 33/108 reads (31%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV53301867, COSV99989648; called by muse, mutect2, varscan2
- XPO6 | c.877A>G p.N293D | Missense Mutation (SNP) | VAF 29/100 reads (29%) | SIFT tolerated (0.65); PolyPhen benign (0); catalogued as COSV100485283; called by muse, mutect2, varscan2
- ZBTB2 | c.1242C>G p.S414R | Missense Mutation (SNP) | VAF 8/57 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.334); catalogued as COSV100287791; called by muse, mutect2
- ZNF318 | c.2636C>T p.S879F | Missense Mutation (SNP) | VAF 24/70 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV100546437, COSV58937491; called by muse, mutect2, varscan2
- ZNF45 | c.1007C>T p.A336V | Missense Mutation (SNP) | VAF 21/72 reads (29%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV99524228; called by muse, mutect2, varscan2
- ZNF45 | c.1006G>A p.A336T | Missense Mutation (SNP) | VAF 19/69 reads (28%) | SIFT tolerated (0.91); PolyPhen benign (0.007); catalogued as COSV99524231; called by muse, mutect2, varscan2
- ZNF470 | c.2048G>A p.G683E | Missense Mutation (SNP) | VAF 12/61 reads (20%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.825); catalogued as COSV100401352; called by muse, mutect2, varscan2
- ZNF547 | c.7G>A p.E3K | Missense Mutation (SNP) | VAF 7/72 reads (10%) | SIFT tolerated (0.94); PolyPhen benign (0.035); catalogued as COSV99988126; called by muse, mutect2, varscan2
- ZNF564 | c.155T>G p.I52S | Missense Mutation (SNP) | VAF 6/41 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.212); catalogued as rs1266228536, COSV100213257; called by muse, mutect2, varscan2
- ZNF616 | c.1493G>A p.C498Y | Missense Mutation (SNP) | VAF 14/114 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100348538; called by muse, mutect2, varscan2
- ADAMTS6 | c.2064C>A p.C688* | Nonsense Mutation (SNP) | VAF 14/28 reads (50%) | called by muse, mutect2, varscan2
- CSMD3 | c.10143dup p.G3382Rfs*15 (on ENST00000297405 / NM_001363185.1; = p.G3213Rfs*15 on NM_052900.3) | Frame Shift Ins (INS) | VAF 15/60 reads (25%) | called by mutect2, pindel, varscan2
- LRP12 | c.2397_2400dup p.D801Lfs*8 | Frame Shift Ins (INS) | VAF 23/96 reads (24%) | called by mutect2, pindel, varscan2
- PRPF38B | c.970_980del p.G324Qfs*6 | Frame Shift Del (DEL) | VAF 22/64 reads (34%) | called by mutect2, pindel
- RBBP4 | c.693_695del p.E231del | In Frame Del (DEL) | VAF 20/75 reads (27%) | called by pindel, varscan2
- SYT16 | c.843dup p.H282Tfs*31 | Frame Shift Ins (INS) | VAF 11/38 reads (29%) | called by mutect2, pindel, varscan2
- TP53 | c.78del p.P27Lfs*17 | Frame Shift Del (DEL) | VAF 24/51 reads (47%) | called by mutect2, pindel, varscan2
- TRBJ2-5 | c.18C>G p.Y6* | Nonsense Mutation (SNP) | VAF 10/22 reads (45%) | called by muse, mutect2, varscan2
- ZGRF1 | c.1042_1044delinsT p.T348* | Frame Shift Del (DEL) | VAF 25/61 reads (41%) | called by pindel, varscan2*
- ACOT9 | c.756C>T p.A252= | Silent (SNP) | VAF 17/65 reads (26%) | catalogued as COSV100321399; called by muse, mutect2, varscan2
- APOBR | c.2328G>C p.V776= (on ENST00000431282; = p.V785= on NM_018690.4) | Silent (SNP) | VAF 10/36 reads (28%) | catalogued as COSV100112814; called by muse, mutect2
- ATP1B2 | c.483C>T p.S161= | Silent (SNP) | VAF 159/293 reads (54%) | catalogued as rs201606347; called by muse, mutect2, varscan2
- BAHCC1 | c.1980C>T p.A660= | Silent (SNP) | VAF 6/20 reads (30%) | catalogued as rs377055909; called by muse, mutect2, varscan2
- CERT1 | c.1473G>C p.G491= (on ENST00000405807 / NM_001130105.1; = p.G363= on NM_005713.3) | Silent (SNP) | VAF 8/19 reads (42%) | catalogued as COSV99783613; called by muse, mutect2, varscan2
- CHKA | c.1356G>A p.K452= | Silent (SNP) | VAF 6/24 reads (25%) | catalogued as COSV99693562; called by muse, mutect2, varscan2
- COMT | c.282C>T p.D94= | Silent (SNP) | VAF 7/47 reads (15%) | catalogued as COSV99258817; called by muse, mutect2
- CSMD1 | c.9609C>T p.S3203= (on ENST00000520002; = p.S3202= on NM_033225.6) | Silent (SNP) | VAF 8/56 reads (14%) | catalogued as rs773511359, COSV100152437; called by mutect2, varscan2
- DNAH5 | c.12402T>C p.A4134= | Silent (SNP) | VAF 27/152 reads (18%) | catalogued as rs1327666188, COSV54222733; called by muse, mutect2, varscan2
- FBN3 | c.8136G>A p.L2712= | Silent (SNP) | VAF 8/23 reads (35%) | catalogued as COSV99495161; called by muse, mutect2
- FRMPD4 | c.2862G>A p.P954= | Silent (SNP) | VAF 83/132 reads (63%) | catalogued as rs1395277243, COSV101043784; called by muse, mutect2, varscan2
- GCLC | c.858C>A p.P286= (on ENST00000643939; = p.P284= on NM_001498.4) | Silent (SNP) | VAF 14/114 reads (12%) | catalogued as COSV57597114; called by muse, mutect2, varscan2
- HLA-DOA | c.129C>T p.G43= | Silent (SNP) | VAF 15/64 reads (23%) | catalogued as rs574592087, COSV57715439; called by muse, mutect2, varscan2
- IL12RB1 | c.384G>A p.E128= | Silent (SNP) | VAF 15/94 reads (16%) | catalogued as COSV100442932; called by muse, mutect2, varscan2
- KCNN1 | c.294G>C p.A98= | Silent (SNP) | VAF 6/28 reads (21%) | catalogued as COSV99716252; called by muse, mutect2, varscan2
- KCNQ1 | c.867C>T p.N289= | Silent (SNP) | VAF 15/35 reads (43%) | catalogued as rs1262523905, COSV99328068; called by muse, mutect2, varscan2
- KNOP1 | c.1131C>G p.L377= | Silent (SNP) | VAF 26/86 reads (30%) | catalogued as COSV99575319; called by muse, mutect2, varscan2
- MUS81 | c.861G>C p.L287= | Silent (SNP) | VAF 3/34 reads (9%) | catalogued as COSV100337361; called by muse, mutect2
- NPC1L1 | c.591C>T p.C197= | Silent (SNP) | VAF 23/90 reads (26%) | catalogued as rs780427494, COSV99213076; called by muse, mutect2, varscan2
- NUP210L | c.3195G>A p.K1065= | Silent (SNP) | VAF 6/74 reads (8%) | catalogued as COSV99668799; called by muse, mutect2
- OR6C70 | c.534C>T p.D178= | Silent (SNP) | VAF 33/135 reads (24%) | catalogued as COSV100524479; called by muse, mutect2, varscan2
- PCDHA13 | c.1512G>A p.L504= | Silent (SNP) | VAF 45/116 reads (39%) | catalogued as COSV99168955; called by muse, mutect2, varscan2
- PRKCH | c.1578C>A p.L526= | Silent (SNP) | VAF 32/184 reads (17%) | catalogued as COSV100273004, COSV100273649; called by muse, mutect2, varscan2
- PROCR | c.438G>A p.E146= | Silent (SNP) | VAF 42/124 reads (34%) | catalogued as rs766151404, COSV99405822; called by muse, mutect2, varscan2
- SCN8A | c.5526C>A p.I1842= | Silent (SNP) | VAF 44/157 reads (28%) | catalogued as COSV100634140; called by muse, mutect2, varscan2
- SEMA3B | c.1797G>A p.A599= | Silent (SNP) | VAF 14/34 reads (41%) | catalogued as COSV100312913; called by muse, mutect2, varscan2
- SHOX2 | c.995G>A p.*332= (on ENST00000441443 / NM_006884.3; = p.*356= on NM_003030.4) | Silent (SNP) | VAF 149/665 reads (22%) | catalogued as COSV101273817, COSV67463890; called by muse, mutect2, varscan2
- SLC38A1 | c.1032A>G p.K344= | Silent (SNP) | VAF 17/62 reads (27%) | catalogued as COSV101284261; called by muse, mutect2, varscan2
- TMEM106B | c.384A>G p.V128= | Silent (SNP) | VAF 45/154 reads (29%) | catalogued as COSV101188864; called by muse, mutect2, varscan2
- ZFHX4 | c.8091G>A p.R2697= | Silent (SNP) | VAF 18/80 reads (23%) | catalogued as COSV99266391; called by muse, mutect2, varscan2
- IFRD2 | chr3:50292645 C>A | 5'Flank (SNP) | VAF 21/55 reads (38%) | catalogued as COSV100269758; called by muse, mutect2, varscan2
- VPS11 | chr11:119067990 G>A | 5'Flank (SNP) | VAF 4/15 reads (27%) | catalogued as COSV100333950; called by mutect2, varscan2
